Somatic mutation profile of tumor specimen C3L-02888-02 (aliquot CPT0166540034) from CPTAC case C3L-02888, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 62.8 years (22,949 days).
Specimen C3L-02888-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a18c9f51-2b9b-4a1a-bf4e-1327788905d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02888-31 (Blood Derived Normal), aliquot CPT0166580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c0f3cdc-f06d-4fe7-9255-1f3db588cb96

The open-access MAF lists 74 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Nonsense Mutation 6, 5'Flank 2, Splice Site 2, Intron 2, 3'Flank 1, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 171/472 reads (36%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYP4F22 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201129618, CM060277, COSV54110996; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.16501C>T p.R5501* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as rs886041398, CM105482, COSV56407191; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 82/396 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 93/293 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684417, COSV61684645, COSV61684738; called by muse, mutect2, varscan2
- TP53 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 137/557 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs377381847; called by muse, mutect2, varscan2
- ACTN3 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs761392416; called by muse, mutect2, varscan2
- ADAM12 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs576203316, COSV64113235; called by muse, mutect2, varscan2
- ADCY4 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs138257439; called by muse, mutect2, varscan2
- CAMLG | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 113/511 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.149); catalogued as COSV99777812; called by muse, mutect2, varscan2
- CCDC88B | c.3926G>A p.R1309Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749137059, COSV57267343; called by muse, mutect2, varscan2
- CHRM3 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV55083588; called by muse, mutect2, varscan2
- CPXCR1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 40/112 reads (36%) | catalogued as COSV52160939; called by muse, mutect2
- DCT | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs750417204; called by muse, mutect2, varscan2
- GDI1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV50130963; called by muse, mutect2, varscan2
- GUCY2D | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as CM155804, COSV54699605; called by muse, mutect2, varscan2
- IRF6 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 46/185 reads (25%) | catalogued as CD022553, CM067420, CM090291; called by muse, mutect2, varscan2
- LMBRD1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 174/588 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV65298480; called by muse, mutect2, varscan2
- MAGEH1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs917411358; called by muse, mutect2, varscan2
- MIB2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs1250293210, COSV61755226; called by muse, mutect2, varscan2
- MMP9 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777794038; called by muse, mutect2, varscan2
- NEURL1B | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as rs939595606, COSV104425029; called by muse, mutect2, varscan2
- PITPNM2 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.718); catalogued as rs551002395, COSV54895410; called by muse, mutect2, varscan2
- PLSCR2 | c.223C>T p.P75S (on ENST00000497985 / NM_001199978.1; = p.P2S on NM_020359.2) | Missense Mutation (SNP) | VAF 136/591 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1410433569; called by muse, mutect2, varscan2
- PRAMEF20 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 24/500 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs962195338; called by muse, mutect2
- RNF150 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 170/555 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99058792; called by muse, mutect2, varscan2
- RYR1 | c.5047G>A p.A1683T | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1455863679, COSV62098288; called by muse, mutect2
- SH3BP5 | c.563A>C p.N188T | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV99508018; called by muse, mutect2, varscan2
- SLC8A2 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1447849965; called by muse, mutect2, varscan2
- SMC1A | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 153/682 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.376); catalogued as COSV100447708; called by muse, mutect2, varscan2
- SMS | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs746297985, COSV65113563; called by muse, mutect2, varscan2
- TEX35 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV51103268; called by muse, mutect2, varscan2
- TNR | c.2068C>T p.R690* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as rs1177595465; called by muse, mutect2, varscan2
- UTP14A | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs749551821; called by muse, mutect2, varscan2
- XYLT2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 68/367 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.34); catalogued as rs763473385, COSV50019905; called by muse, mutect2, varscan2
- ZMYM3 | c.3562C>T p.R1188* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV58739562; called by mutect2, varscan2
- ANK1 | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASPH | c.415+1G>A p.X139_splice | Splice Site (SNP) | VAF 74/340 reads (22%) | called by muse, mutect2, varscan2
- EBAG9 | c.352T>G p.F118V | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FABP9 | c.242T>G p.V81G | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- FYB1 | c.1818C>T p.S606= | Splice Region (SNP) | VAF 43/222 reads (19%) | called by muse, mutect2, varscan2
- KAT6A | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 197/629 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LYST | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MALRD1 | c.5105T>A p.L1702H | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- MICALL2 | c.2576A>G p.D859G | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NCOR2 | c.4937-1G>A p.X1646_splice | Splice Site (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2
- OSCAR | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 134/317 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PAFAH2 | c.1144A>G p.T382A | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- RNF10 | c.2408T>G p.F803C | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA6A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEPTIN7 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SHROOM2 | c.4559A>G p.D1520G | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARG2 | c.828C>T p.G276= | Silent (SNP) | VAF 31/170 reads (18%) | called by muse, mutect2, varscan2
- CHST2 | c.531G>A p.S177= | Silent (SNP) | VAF 67/230 reads (29%) | catalogued as rs368136453; called by muse, mutect2, varscan2
- DPYSL3 | c.156C>T p.F52= | Silent (SNP) | VAF 81/348 reads (23%) | catalogued as COSV100574882, COSV58330595; called by muse, mutect2, varscan2
- F2RL2 | c.57T>C p.C19= | Silent (SNP) | VAF 80/331 reads (24%) | called by muse, mutect2, varscan2
- ITGAX | c.2493C>T p.Y831= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs146985733; called by muse, mutect2, varscan2
- LRSAM1 | c.1299G>T p.S433= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as rs755070977; called by muse, mutect2, varscan2
- MAGEL2 | c.3549C>T p.L1183= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV58565766; called by muse, mutect2, varscan2
- NKAPL | c.417G>A p.P139= | Silent (SNP) | VAF 52/179 reads (29%) | catalogued as COSV59197910; called by muse, mutect2, varscan2
- PARP14 | c.5157C>T p.A1719= | Silent (SNP) | VAF 39/182 reads (21%) | called by muse, mutect2, varscan2
- PCDHA7 | c.429G>A p.A143= | Silent (SNP) | VAF 76/298 reads (26%) | called by muse, mutect2, varscan2
- SPTBN5 | c.9903G>A p.A3301= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as rs771946309; called by muse, mutect2, varscan2
- TEX13C | c.594C>T p.A198= | Silent (SNP) | VAF 54/279 reads (19%) | called by muse, mutect2, varscan2
- THOC2 | c.2574G>A p.A858= | Silent (SNP) | VAF 83/425 reads (20%) | catalogued as rs763790733; called by muse, mutect2, varscan2
- TRMT61B | c.717C>A p.L239= | Silent (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2, varscan2
- AC235097.1 | n.504G>A | RNA (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- ASCC1 | chr10:72216997 ins CTC | 5'Flank (INS) | VAF 42/316 reads (13%) | called by mutect2, pindel, varscan2
- CEP57 | c.1273-50del | Intron (DEL) | VAF 31/165 reads (19%) | catalogued as rs760000276; called by mutect2, pindel, varscan2
- HIF3A | c.877+119C>T | Intron (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- IMPDH1 | chr7:128409773 G>T | 5'Flank (SNP) | VAF 17/492 reads (3%) | catalogued as rs1192233344; called by muse, mutect2
- RNU6-817P | chr1:116410102 C>T | 3'Flank (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- SPAG11B | c.*68C>T | 3'UTR (SNP) | VAF 48/682 reads (7%) | catalogued as rs1433304287, COSV52499308; called by muse, mutect2
